Gene-level copy-number profile of tumor specimen TCGA-NA-A4R1-01A from TCGA case TCGA-NA-A4R1, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinosarcoma, NOS; Tissue or organ of origin: Uterus, NOS; FIGO stage: Stage IIIC1; Age at diagnosis: 75.8 years (27,688 days).
Specimen TCGA-NA-A4R1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.4b7aa468-4b8f-45a2-a072-d774c7a8a1ff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NA-A4R1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bc525a04-3684-4893-ac88-37c8295eed74

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 415; copy number 2: 13,883; copy number 3: 4,896; copy number 4: 32,419; copy number 5: 3,174; copy number 6: 3,869; copy number 7: 308; copy number 8: 423; copy number 9: 114; copy number 10: 77; copy number 11: 204; copy number 12: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NA-A4R1-01A-11D-A28Q-01): tumor purity 0.97, ploidy 3.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:12,312,588–12,864,961, 4 genes: RNU6-578P, ECM1P2, AC093809.1, AC007370.2.
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 405 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,482,238–148,288,951, 29 genes, copy number 9: OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2, RNVU1-22, LINC01731, AC245100.3.
- chr1:148,295,180–148,358,686, 7 genes, copy number 9: LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6.
- chr5:174,045,706–174,995,513, 18 genes, copy number 9: NSG2, AC113423.1, AC113423.2, AC011333.1, AC025752.1, LINC01411, GAPDHP71, SUMO2P6, AC108112.1, HIGD1AP3, MSX2, AC113346.2, MIR4634, AC113346.1, LINC01951, NIFKP2, AC008413.1, AC008413.2.
- chr7:70,972–95,683, 2 genes, copy number 9: AC093627.1, AC093627.6.
- chr7:95,772,506–96,322,147, 4 genes, copy number 12 (within-gene range 6–12): DYNC1I1, AC002540.1, SLC25A13, MIR591.
- chr7:104,328,700–104,926,645, 6 genes, copy number 12 (within-gene range 6–12): LHFPL3, EIF4BP6, LHFPL3-AS1, AC091286.1, LHFPL3-AS2, RN7SL8P.
- chr7:105,530,209–106,770,207, 18 genes, copy number 11 (within-gene range 6–11): AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1, RNU6-392P, NAMPT, AC007032.1, LARP1BP2, AC004917.1, AC005050.3, AC005050.1.
- chr7:107,168,961–108,952,666, 33 genes, copy number 10 (within-gene range 6–10): HBP1, AC004492.1, COG5, AC002381.1, GPR22, DUS4L, DUS4L-BCAP29, AC004839.2, BCAP29, AC004839.1, WBP1LP2, BANF1P5, SLC26A4-AS1, SLC26A4, AC002467.1, CBLL1, SLC26A3, PIGCP2, DLD, LAMB1, AC005046.1, U3, LAMB4, NRCAM, PNPLA8, RPL7P32, THAP5, DNAJB9, AC005487.1, AC002487.1, C7orf66, AC004014.2, AC004014.1.
- chr7:129,604,548–130,506,465, 32 genes, copy number 11: AC078846.1, NRF1, RNA5SP244, AC084864.2, MIR182, MIR96, MIR183, AC084864.1, UBE2H, AC073320.1, Y_RNA, ZC3HC1, RNA5SP245, KLHDC10, AC087071.1, TMEM209, AC087071.2, SSMEM1, AC024085.1, CPA2, CPA4, CPA5, CPA1, CEP41, AC007938.1, MESTIT1, MEST, AC007938.5, AC007938.6, AC007938.4, AC007938.2, MIR335.
- chr7:130,507,660–130,508,282, 1 gene, copy number 11: AC007938.3.
- chr7:138,831,381–139,777,998, 22 genes, copy number 9 (within-gene range 6–9): KIAA1549, RNU6-1272P, ZC3HAV1L, ZC3HAV1, AC018644.1, TTC26, AC009220.2, AC009220.3, AC009220.1, MZT1P2, UBN2, RNU6-206P, FMC1, LUC7L2, FMC1-LUC7L2, AC083880.1, RNU6-911P, KLRG2, AC005531.1, CLEC2L, ERHP1, HIPK2.
- chr7:148,963,315–149,497,817, 23 genes, copy number 10: RNY4, RNY3, RNY1, GHET1, PDIA4, RNU6-650P, COX6B1P1, ZNF786, ZNF425, RN7SL521P, ZNF398, AC004890.1, ZNF282, ZNF212, ZNF783, AC004890.3, AC004890.2, AC004941.2, NPM1P12, AC004941.1, AC073314.1, ZNF777, ZNF746.
- chr7:151,148,589–151,916,418, 25 genes, copy number 11: GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1, NUB1, WDR86, WDR86-AS1, AC005996.1, CRYGN, MIR3907, RN7SL76P, RHEB, ETF1P2, PRKAG2, AC093583.1, PRKAG2-AS1, RNU6-604P, Y_RNA.
- chr8:129,415,949–130,655,712, 21 genes, copy number 10: AC011257.1, MIR3686, AC103718.1, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr12:43,718,992–46,373,778, 36 genes, copy number 11: PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2.
- chr12:46,384,233–46,407,166, 3 genes, copy number 11: AC025031.1, AC025031.4, AC025031.5.
- chr17:50,346,126–50,910,774, 36 genes, copy number 9 (within-gene range 3–9): XYLT2, AC015909.5, MRPL27, EME1, LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1, CACNA1G, AC021491.3, AC004590.1, ABCC3, ANKRD40, AC005921.2, Y_RNA, LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1.
- chr19:51,804,816–53,392,217, 89 genes, copy number 11 (within-gene range 8–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 415. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
